Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4701, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4701-01A (Primary Tumor).

FINAL DIAGNOSIS:

- KIDNEY, ADRENAL GLAND, AND PERI-AORTIC LYMPH NODES, LEFT, LAPAROSCOPIC RADICAL NEPHRECTOMY –
- A. CONVENTIONAL (CLEAR CELL) RENAL CELL CARCINOMA WITH FOCAL TUBULOPAPILLARY AND SARCOMATOID FEATURES.
- B. FUHRMAN NUCLEAR GRADE 3-4/ 4.
- C. TUMOR IS 11 CM IN GREATEST DIMENSION.
- D. TUMOR INVADES PERINEPHRIC ADIPOSE TISSUE.
- E. FOCAL MICROSCOPIC ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- F. THE TUMOR APPROACHES VERY CLOSE TO THE SURGICAL MARGINS OF RESECTION (LESS THAN 1 HIGH POWER FIELD). HOWEVER NO TUMOR IS SEEN AT THE INKED MARGIN OF RESECTION.
- G. EXTENSIVE SAMPLING OF PERINEPHRIC ADIPOSE TISSUE REVEALS ONE BENIGN LYMPH NODE (0/1).
- H. FOCAL COLLECTION OF NEUTROPHILS WITHIN PERINEPHRIC ADIPOSE TISSUE CONSISTENT WITH MICROABSCCESS; CLINICAL AND MICROBIOLOGICAL CORRELATION IS SUGGESTED.
- I. ADRENAL GLAND, WITH NO SIGNIFICANT PATHOLOGIC CHANGE.
- J. MILD TO MODERATE ATHEROSCLEROSIS OF RENAL ARTERY.
- K. PATHOLOGIC STAGE: T3a N0 Mx.

Source: NCI Genomic Data Commons file 2c2a6c96-e9b2-40ba-8db2-6a17d3101b2c (TCGA-B0-4701.9E5FFC32-586B-439A-A12A-0D729C18BD11.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).